Somatic mutation profile of tumor specimen TCGA-FK-A3SD-01A (aliquot TCGA-FK-A3SD-01A-11D-A22D-08) from TCGA case TCGA-FK-A3SD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 61.8 years (22,560 days).
Specimen TCGA-FK-A3SD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a94495ad-058c-45b9-94bc-28b731002083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FK-A3SD-10A (Blood Derived Normal), aliquot TCGA-FK-A3SD-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a5c48c7-fef4-41a2-9868-f33169e46084

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- ARMC3 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV53061170; called by muse, mutect2, varscan2
- ELMO1 | c.1099C>G p.P367A | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60304263, COSV60320230; called by muse, mutect2, varscan2
- ITPR2 | c.4583C>T p.A1528V | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs200190856, COSV67269197; called by muse, mutect2
- MYO1C | c.1226C>T p.P409L (on ENST00000648651 / NM_001080779.2; = p.P374L on NM_033375.5) | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV62999091; called by muse, mutect2
- PA2G4 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57253114; called by muse, varscan2
- PRKD1 | c.568T>C p.F190L | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV59568540; called by muse, mutect2
- SRPRA | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs1231931640, COSV55006527; called by muse, mutect2
- UGT2B7 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59443396; called by muse, mutect2, varscan2
- ZBTB22 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.286); catalogued as COSV56469226; called by muse, mutect2
- ZC3H12C | c.2099A>G p.K700R | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV53708728; called by muse, mutect2
- ZNF611 | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 22/491 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60540815; called by muse, mutect2
- LSR | c.942A>T p.A314= (on ENST00000361790; = p.A295= on NM_015925.6) | Silent (SNP) | VAF 10/272 reads (4%) | catalogued as COSV55887015; called by muse, mutect2
- TBC1D22B | c.840G>A p.P280= | Silent (SNP) | VAF 85/200 reads (43%) | catalogued as rs74511891, COSV65142772; called by muse, mutect2, varscan2
- TMPRSS11B | c.15C>T p.G5= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs968331903, COSV60292350; called by muse, mutect2, varscan2
